Surgical pathology report (de-identified scan), TCGA case TCGA-SP-A6QC, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Health Network, specimen TCGA-SP-A6QC-01A (Primary Tumor).

[page 1 of 2]
Y MEDICINE PROGRAM

Surgical Pathology Consultation Report * Added *

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Collected:	
DOB:	[REDACTED]	Received:	
Gender:	[REDACTED]	Location:	
HCN:	[REDACTED]	Facility:	
Ordering MD:		Reported:	
Copy To:			

Specimen(s) Received

1. Adrenal: Left Resection

Diagnosis

Adrenal, Left Adrenalectomy;
-PHEOCHROMOCYTOMA (see comment and microscopic description)

Comment

Immunohistochemical stains (Synaptophysin, chromogranin, S100) will be performed and a supplementary report will be issued when these are complete.

Electronically verified by:

Clinical History

Pheochromocytoma

Gross Description

The specimen container labeled with the patient's name and as "left resection", contains a tan tumor mass with fibrous adhesion on the capsular surface as well as some adipose tissue received in 10% buffered formalin. The specimen weighs 95.0 grams and is painted with silver nitrate. It measures 6.0 x 6.0 x 3.0 cm. The capsular surface of the tumor mass is composed of yellow adrenal tissue. The cut surface and content of the mass is solid and rubbery as well as dark brown. There are diffuse cystic spaces in the specimen ranging in size from 0.1 cm in diameter up to 1.0 cm in diameter. One piece of tumor and one piece of adrenal gland are taken for tissue banking.

1A -H representative sections.

Microscopic Description

Sections show a tumor composed of large polygonal cells arranged in nests and trabeculae. In areas, these structures are separated by fibrovascular septa, forming a Zellballen pattern. In other areas, there is marked sinusoidal dilation within the septa. The cells exhibit predominantly a granular basophilic cytoplasm, with oval and round nuclei, containing vesicular chromatin and small nucleoli. In one area, marked nuclear pleomorphism is seen, including nuclear gigantism.

[page 2 of 2]
Surgical Pathology Consultation Report

Foci of hyaline globules, and melanin pigment within the cytoplasm are seen in some cells. There are areas of hemorrhage in the specimen. The tumor is present at the painted margins. There is no evidence of lymphovascular invasion. The above morphologic and histologic features are that of a pheochromocytoma.

Addendum

Status: Signed Out

Date Reported:

Addendum Comment

Immunohistochemical stains show that the tumor is strongly synaptophysin and chromogranin positive. There is S100 positivity primarily in the intervening sustentacular cells within the tumor. The above immunohistochemical stains are consistent with the diagnosis of a pheochromocytoma.

Source: NCI Genomic Data Commons file 398374d6-6050-4f08-9b5c-80bb9112ac89 (TCGA-SP-A6QC.E79EE6B9-75BB-463B-8379-C4E1564FC664.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).